Somatic mutation profile of tumor specimen MMRF_2705_1_BM_CD138pos (aliquot MMRF_2705_1_BM_CD138pos_T1_KHS5U_L14436) from MMRF case MMRF_2705, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 65.2 years (23,813 days).
Specimen MMRF_2705_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a85cd49d-2cce-47c6-9c4a-057e6c7c8d2c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2705_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2705_1_PB_WBC_C2_KHS5U_L14437; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1233fa10-d615-40da-898c-31e304ec9ea5

The open-access MAF lists 147 somatic variants for this specimen: 55 protein-altering or splice-affecting, 16 silent, 76 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, 3'UTR 36, Intron 21, Silent 16, 5'Flank 6, 3'Flank 5, 5'UTR 5, Nonsense Mutation 3, RNA 3, Frame Shift Del 2, Splice Site 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EDNRB | c.823G>A p.V275M (on ENST00000377211 / NM_001201397.1; = p.V185M on NM_000115.5) | Missense Mutation (SNP) | VAF 51/109 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs781214034, CM081580, COSV57520197, COSV57528867; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- TP53 | c.644G>C p.S215T | Missense Mutation (SNP) | VAF 59/80 reads (74%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587782177, COSV52679681, COSV52686793, COSV52700292, COSV52891297; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANKRD33B | c.1351G>A p.G451S | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as rs1467727936; called by muse, mutect2, varscan2
- CHRD | c.1814C>A p.S605* | Nonsense Mutation (SNP) | VAF 14/133 reads (11%) | catalogued as COSV52608986, COSV52610032; called by muse, mutect2, varscan2
- FER1L6 | c.2451C>A p.N817K | Missense Mutation (SNP) | VAF 15/23 reads (65%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs1413237797; called by muse, mutect2, varscan2
- FETUB | c.641C>T p.S214L | Missense Mutation (SNP) | VAF 29/146 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV54005119; called by muse, mutect2, varscan2
- FOCAD | c.2315C>T p.P772L | Missense Mutation (SNP) | VAF 68/718 reads (9%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.629); catalogued as rs1302395983; called by muse, mutect2
- GPR78 | c.712C>T p.R238C | Missense Mutation (SNP) | VAF 47/215 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs749861236, COSV101223942; called by muse, mutect2, varscan2
- IGHD1-1 | c.4A>G p.T2A | Missense Mutation (SNP) | VAF 12/15 reads (80%) | PolyPhen benign (0.003); catalogued as rs532419564; called by muse, mutect2
- IGHD1-1 | c.2G>A p.G1D | Missense Mutation (SNP) | VAF 12/15 reads (80%) | PolyPhen benign (0.003); catalogued as rs367635597; called by muse, mutect2
- IGHV2-70 | c.286A>G p.K96E | Missense Mutation (SNP) | VAF 44/52 reads (85%) | SIFT deleterious (0.01); PolyPhen benign (0.351); catalogued as rs184904469; called by muse, varscan2
- IGHV2-70 | c.229G>T p.D77Y | Missense Mutation (SNP) | VAF 80/88 reads (91%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.646); catalogued as rs369066675; called by muse, varscan2
- IGKJ4 | c.19A>T p.T7S | Missense Mutation (SNP) | VAF 51/96 reads (53%) | PolyPhen benign (0.055); catalogued as rs371061461; called by muse, mutect2, varscan2
- KLHL17 | c.386G>A p.R129H | Missense Mutation (SNP) | VAF 54/126 reads (43%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as rs1236510916; called by muse, mutect2, varscan2
- LAMA1 | c.3152C>T p.S1051L | Missense Mutation (SNP) | VAF 74/398 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs758572977, COSV101056040; called by muse, mutect2, varscan2
- MS4A15 | c.227C>T p.T76M | Missense Mutation (SNP) | VAF 72/251 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as rs1338932482; called by muse, mutect2, varscan2
- MYH4 | c.52C>T p.R18* | Nonsense Mutation (SNP) | VAF 46/68 reads (68%) | catalogued as rs373223401; called by muse, mutect2, varscan2
- NDUFA11 | c.334G>A p.A112T | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT tolerated (0.97); PolyPhen probably damaging (0.923); catalogued as rs202097097; called by muse, mutect2, varscan2
- PKHD1 | c.10327A>G p.S3443G | Missense Mutation (SNP) | VAF 86/223 reads (39%) | SIFT tolerated (0.41); PolyPhen benign (0.006); catalogued as rs755692013, COSV64402165; called by muse, mutect2, varscan2
- PRUNE2 | c.5656C>T p.P1886S | Missense Mutation (SNP) | VAF 43/214 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.573); catalogued as COSV100945311, COSV65044184; called by muse, mutect2, varscan2
- PTPRG | c.218C>T p.T73M | Missense Mutation (SNP) | VAF 42/136 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.59); catalogued as rs182010071, COSV55662828; called by muse, mutect2, varscan2
- SI | c.4268-1G>A p.X1423_splice | Splice Site (SNP) | VAF 11/39 reads (28%) | catalogued as COSV100013222; called by muse, mutect2, varscan2
- SLIT2 | c.1816G>A p.E606K | Missense Mutation (SNP) | VAF 41/103 reads (40%) | SIFT tolerated (0.62); PolyPhen benign (0.222); catalogued as rs1357508065; called by muse, mutect2, varscan2
- TOGARAM1 | c.4401-1G>A p.X1467_splice | Splice Site (SNP) | VAF 31/68 reads (46%) | catalogued as rs1476624357; called by muse, mutect2, varscan2
- AC127029.3 | c.833A>G p.N278S | Missense Mutation (SNP) | VAF 102/245 reads (42%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- ADAMTSL4 | c.941A>G p.Q314R | Missense Mutation (SNP) | VAF 61/124 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- AFP | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 54/130 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BRINP1 | c.2201A>G p.E734G | Missense Mutation (SNP) | VAF 18/165 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- FAM200A | c.761C>T p.S254L | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- HLA-DPB1 | c.580C>T p.Q194* | Nonsense Mutation (SNP) | VAF 25/186 reads (13%) | called by muse, mutect2, varscan2
- HOXA6 | c.59C>A p.S20Y | Missense Mutation (SNP) | VAF 82/201 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); called by muse, mutect2, varscan2
- HSPG2 | c.6938C>T p.A2313V | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT tolerated (0.33); PolyPhen benign (0.426); called by muse, mutect2
- HUWE1 | c.2188G>A p.E730K | Missense Mutation (SNP) | VAF 6/95 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.825); called by muse, mutect2
- IGKV4-1 | c.47C>G p.S16C | Missense Mutation (SNP) | VAF 32/66 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); called by muse, varscan2
- ITIH6 | c.2380C>A p.L794I | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT tolerated (0.44); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KIF7 | c.1232G>A p.R411H | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated (0.83); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KNL1 | c.4352T>C p.L1451P (on ENST00000346991 / NM_170589.5; = p.L1425P on NM_144508.5) | Missense Mutation (SNP) | VAF 33/119 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- KRT36 | c.1276C>T p.P426S | Missense Mutation (SNP) | VAF 41/88 reads (47%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRRK1 | c.3200G>T p.G1067V | Missense Mutation (SNP) | VAF 60/213 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- MYO16 | c.4763G>T p.R1588M | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- NAV3 | c.6562T>G p.L2188V (on ENST00000397909 / NM_001024383.2; = p.L2166V on NM_014903.6) | Missense Mutation (SNP) | VAF 147/324 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NNT | c.2521T>G p.Y841D | Missense Mutation (SNP) | VAF 33/58 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PEG3 | c.3160G>C p.D1054H | Missense Mutation (SNP) | VAF 23/218 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.258); called by muse, mutect2
- PLCD3 | c.2253T>A p.F751L | Missense Mutation (SNP) | VAF 10/105 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.371); called by muse, mutect2
- POLD4 | c.81G>C p.E27D | Missense Mutation (SNP) | VAF 56/164 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- POR | c.1213C>A p.L405M | Missense Mutation (SNP) | VAF 8/176 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.906); called by muse, mutect2
- RAPGEF4 | c.2905T>G p.F969V | Missense Mutation (SNP) | VAF 82/193 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- RASGRF2 | c.3642C>A p.D1214E | Missense Mutation (SNP) | VAF 46/330 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- RPA4 | c.762_763insA p.E255Rfs*4 | Frame Shift Ins (INS) | VAF 30/248 reads (12%) | called by mutect2, pindel*, varscan2
- SCN10A | c.2112del p.F704Lfs*36 | Frame Shift Del (DEL) | VAF 79/261 reads (30%) | called by mutect2, pindel, varscan2
- SNX2 | c.214G>A p.D72N | Missense Mutation (SNP) | VAF 29/214 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SRPX2 | c.1231_1262del p.L411* | Frame Shift Del (DEL) | VAF 59/138 reads (43%) | called by mutect2, pindel
- SUCNR1 | c.284G>C p.C95S | Missense Mutation (SNP) | VAF 80/310 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TPRG1 | c.37G>T p.V13L | Missense Mutation (SNP) | VAF 224/378 reads (59%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- ZNF534 | c.227A>T p.K76M (on ENST00000332323 / NM_001143939.3; = p.K63M on NM_001143938.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 68/266 reads (26%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.598); called by muse, mutect2, varscan2
- ABCA7 | c.4362C>T p.V1454= | Silent (SNP) | VAF 15/117 reads (13%) | called by muse, mutect2, varscan2
- ADAMTSL1 | c.3132G>A p.A1044= | Silent (SNP) | VAF 94/370 reads (25%) | catalogued as rs751072322, COSV101001120; called by muse, varscan2
- ATP1A3 | c.243C>T p.N81= (on ENST00000545399 / NM_001256214.2; = p.N68= on NM_152296.5) | Silent (SNP) | VAF 46/182 reads (25%) | catalogued as rs148043407; ClinVar: likely benign; called by muse, mutect2, varscan2
- ERICH6B | c.915G>A p.P305= | Silent (SNP) | VAF 14/95 reads (15%) | catalogued as rs768676117, COSV53922682; called by muse, mutect2, varscan2
- HMCN2 | c.4932G>A p.A1644= | Silent (SNP) | VAF 37/283 reads (13%) | catalogued as rs761248392; called by muse, mutect2, varscan2
- P2RY2 | c.945C>T p.R315= | Silent (SNP) | VAF 43/176 reads (24%) | catalogued as rs771589233, COSV100232869; called by muse, mutect2, varscan2
- PCDH11X | c.1593A>G p.E531= | Silent (SNP) | VAF 123/268 reads (46%) | called by muse, mutect2, varscan2
- PLCH1 | c.948A>G p.T316= (on ENST00000340059 / NM_001130960.2; = p.T328= on NM_014996.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 23/99 reads (23%) | catalogued as rs148522976; called by muse, mutect2, varscan2
- RNF165 | c.273G>A p.Q91= | Silent (SNP) | VAF 32/147 reads (22%) | called by muse, mutect2, varscan2
- SAFB2 | c.1891C>A p.R631= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as rs1306823337, COSV53043866, COSV99385989; called by muse, mutect2
- SLC6A5 | c.1965G>A p.V655= | Silent (SNP) | VAF 82/147 reads (56%) | catalogued as rs755416411; called by muse, mutect2, varscan2
- SSTR1 | c.495G>A p.A165= | Silent (SNP) | VAF 102/212 reads (48%) | catalogued as rs1354643176; called by muse, mutect2, varscan2
- ST6GAL2 | c.1443G>A p.A481= | Silent (SNP) | VAF 52/104 reads (50%) | catalogued as rs367555800, COSV62417302; called by muse, mutect2, varscan2
- SYTL5 | c.1428A>T p.T476= | Silent (SNP) | VAF 46/106 reads (43%) | called by muse, mutect2, varscan2
- TACR1 | c.1146G>T p.L382= | Silent (SNP) | VAF 35/83 reads (42%) | called by muse, mutect2, varscan2
- TFE3 | c.504C>A p.P168= | Silent (SNP) | VAF 9/89 reads (10%) | called by muse, mutect2, varscan2
- ABLIM1 | chr10:114433902 C>A | 3'Flank (SNP) | VAF 30/73 reads (41%) | called by muse, mutect2, varscan2
- ACP4 | chr19:50798328 T>C | 3'Flank (SNP) | VAF 47/221 reads (21%) | catalogued as rs1195217446; called by muse, mutect2, varscan2
- ADAMTS5 | c.*1319_*1322del | 3'UTR (DEL) | VAF 31/131 reads (24%) | called by mutect2, pindel, varscan2
- AL359878.1 | n.552G>A | RNA (SNP) | VAF 12/90 reads (13%) | called by muse, mutect2, varscan2
- AP000769.5 | chr11:65499555 G>A | 5'Flank (SNP) | VAF 71/228 reads (31%) | catalogued as rs1249613371; called by muse, mutect2, varscan2
- AP000769.5 | chr11:65499770 A>G | 5'Flank (SNP) | VAF 18/78 reads (23%) | catalogued as rs1442383076; called by muse, mutect2, varscan2
- APBB3 | c.632+41C>T | Intron (SNP) | VAF 92/173 reads (53%) | catalogued as rs1427850924; called by muse, varscan2
- ARID4A | c.*1877A>G | 3'UTR (SNP) | VAF 21/33 reads (64%) | catalogued as rs1262241880; called by muse, mutect2, varscan2
- ARIH2 | chr3:48918705 T>A | 5'Flank (SNP) | VAF 50/172 reads (29%) | called by muse, mutect2, varscan2
- BCAR1 | chr16:75267942 C>A | 5'Flank (SNP) | VAF 28/59 reads (47%) | called by muse, mutect2, varscan2
- CALN1 | c.*6625A>T | 3'UTR (SNP) | VAF 37/83 reads (45%) | catalogued as rs528980100; called by muse, mutect2, varscan2
- CCSER1 | c.2011-34894A>G | Intron (SNP) | VAF 9/15 reads (60%) | called by muse, mutect2, varscan2
- CEP162 | c.-19G>T | 5'UTR (SNP) | VAF 14/153 reads (9%) | called by muse, mutect2
- CSRNP3 | c.*4529G>T | 3'UTR (SNP) | VAF 23/48 reads (48%) | called by muse, mutect2, varscan2
- CSTF3 | chr11:33081190 A>C | 3'Flank (SNP) | VAF 60/211 reads (28%) | called by muse, mutect2, varscan2
- DAGLA | c.*1529G>A | 3'UTR (SNP) | VAF 40/304 reads (13%) | called by muse, mutect2, varscan2
- DERL2 | chr17:5486189 C>T | 5'Flank (SNP) | VAF 17/21 reads (81%) | called by muse, mutect2, varscan2
- EDEM3 | c.*3123A>G | 3'UTR (SNP) | VAF 42/94 reads (45%) | called by muse, mutect2, varscan2
- FAM131B | c.-56-28C>T | Intron (SNP) | VAF 11/97 reads (11%) | called by muse, mutect2, varscan2
- FAM210A | c.*169C>T | 3'UTR (SNP) | VAF 7/109 reads (6%) | catalogued as rs1053284335; called by muse, mutect2
- FAM76B | c.87+26G>A | Intron (SNP) | VAF 19/84 reads (23%) | called by muse, mutect2, varscan2
- FGFR2 | c.*294C>G | 3'UTR (SNP) | VAF 41/381 reads (11%) | catalogued as COSV100337134; called by muse, mutect2, varscan2
- FMR1 | c.-48C>T | 5'UTR (SNP) | VAF 10/28 reads (36%) | called by muse, mutect2, varscan2
- FOXR2 | c.*39T>G | 3'UTR (SNP) | VAF 123/308 reads (40%) | called by muse, mutect2, varscan2
- GRB2 | c.*593T>A | 3'UTR (SNP) | VAF 6/39 reads (15%) | called by mutect2, varscan2
- HOMER1 | c.-653C>A | 5'UTR (SNP) | VAF 47/120 reads (39%) | called by muse, mutect2, varscan2
- HYDIN | c.-23-16973G>C | Intron (SNP) | VAF 6/19 reads (32%) | called by muse, mutect2, varscan2
- INHBA | c.*4443C>T | 3'UTR (SNP) | VAF 25/51 reads (49%) | called by muse, mutect2, varscan2
- KCNE4 | c.*926G>A | 3'UTR (SNP) | VAF 62/168 reads (37%) | catalogued as rs1263477766; called by muse, mutect2, varscan2
- KCNH2 | c.1128+1822G>C | Intron (SNP) | VAF 8/23 reads (35%) | called by muse, mutect2, varscan2
- KCNK1 | c.*822A>T | 3'UTR (SNP) | VAF 39/90 reads (43%) | called by muse, mutect2, varscan2
- KCNN2 | c.*221C>T | 3'UTR (SNP) | VAF 32/81 reads (40%) | called by muse, mutect2, varscan2
- KIAA1143P1 | n.292C>G | RNA (SNP) | VAF 30/63 reads (48%) | called by muse, mutect2, varscan2
- KLF12 | c.*7317A>G | 3'UTR (SNP) | VAF 27/64 reads (42%) | called by muse, mutect2, varscan2
- LAMC3 | c.*294G>C | 3'UTR (SNP) | VAF 22/133 reads (17%) | called by muse, mutect2, varscan2
- LRRC7 | c.*1096T>C | 3'UTR (SNP) | VAF 32/75 reads (43%) | catalogued as COSV99228741; called by muse, mutect2, varscan2
- MAOB | c.*456C>T | 3'UTR (SNP) | VAF 31/70 reads (44%) | called by muse, mutect2, varscan2
- MIR5195 | chr14:106851258 C>T | 5'Flank (SNP) | VAF 87/178 reads (49%) | catalogued as rs147455610; called by muse, mutect2, varscan2
- MKS1 | c.1096-61G>A | Intron (SNP) | VAF 5/25 reads (20%) | called by muse, mutect2, varscan2
- MTND6P20 | chr8:46843358 G>T | 3'Flank (SNP) | VAF 18/180 reads (10%) | called by muse, mutect2
- NCALD | c.*2209G>A | 3'UTR (SNP) | VAF 29/70 reads (41%) | catalogued as rs957408753; called by muse, mutect2, varscan2
- NDC1 | c.*310A>G | 3'UTR (SNP) | VAF 21/53 reads (40%) | called by muse, mutect2, varscan2
- NDUFB9 | c.294+16G>A | Intron (SNP) | VAF 45/136 reads (33%) | catalogued as rs767465749; called by muse, varscan2
- NDUFB9 | c.408+118G>C | Intron (SNP) | VAF 36/97 reads (37%) | called by muse, varscan2
- NDUFB9 | c.408+213G>C | Intron (SNP) | VAF 38/85 reads (45%) | called by muse, mutect2, varscan2
- NLGN1 | c.*3605G>A | 3'UTR (SNP) | VAF 21/61 reads (34%) | called by muse, mutect2, varscan2
- NRXN1 | c.832+3878A>C | Intron (SNP) | VAF 22/64 reads (34%) | called by muse, mutect2, varscan2
- NUDT4 | c.*1144T>G | 3'UTR (SNP) | VAF 60/296 reads (20%) | catalogued as rs547418041; called by muse, mutect2, varscan2
- OGDHL | c.2392-10G>A | Intron (SNP) | VAF 68/140 reads (49%) | catalogued as rs763433816, COSV65105295, COSV65105333; called by muse, mutect2, varscan2
- PGR | c.*4831G>C | 3'UTR (SNP) | VAF 28/114 reads (25%) | called by muse, mutect2, varscan2
- PKM | c.1141-286G>A | Intron (SNP) | VAF 6/18 reads (33%) | called by muse, mutect2
- PLEKHA5 | c.228-53514A>T | Intron (SNP) | VAF 54/245 reads (22%) | called by muse, mutect2, varscan2
- PPP2R2D | c.*153C>A | 3'UTR (SNP) | VAF 20/45 reads (44%) | catalogued as COSV70778608; called by muse, mutect2, varscan2
- PRDM15 | c.-862G>A | 5'UTR (SNP) | VAF 12/125 reads (10%) | catalogued as rs780009477; called by muse, mutect2
- PSMD12 | c.*1196A>T | 3'UTR (SNP) | VAF 5/71 reads (7%) | called by muse, mutect2
- RAD51D | c.345+83G>A | Intron (SNP) | VAF 7/14 reads (50%) | catalogued as rs973917201; called by muse, varscan2
- RBFOX2 | c.*2905T>G | 3'UTR (SNP) | VAF 4/28 reads (14%) | called by muse, mutect2, varscan2
- REST | c.*911C>T | 3'UTR (SNP) | VAF 14/85 reads (16%) | catalogued as rs1200026980; called by muse, mutect2, varscan2
- RGL2 | c.156+333G>T | Intron (SNP) | VAF 8/148 reads (5%) | called by muse, mutect2
- RNF217-AS1 | n.4209A>C | RNA (SNP) | VAF 6/14 reads (43%) | called by muse, mutect2, varscan2
- S100A2 | c.-10-135A>C | Intron (SNP) | VAF 5/11 reads (45%) | called by muse, mutect2, varscan2
- SIX4 | c.*748_*752del | 3'UTR (DEL) | VAF 32/80 reads (40%) | catalogued as rs569594189; called by mutect2, pindel, varscan2
- SLC7A10 | c.789-10C>T | Intron (SNP) | VAF 71/270 reads (26%) | called by muse, mutect2, varscan2
- SOX11 | c.*4516A>G | 3'UTR (SNP) | VAF 15/45 reads (33%) | called by muse, mutect2, varscan2
- SPATA31C1 | n.523-18_523-17insATCATCTTGTCTCCCAGC | Intron (INS) | VAF 46/177 reads (26%) | catalogued as rs746661893; called by muse*, mutect2, varscan2*
- SPATA31C1 | n.523-17G>A | Intron (SNP) | VAF 36/244 reads (15%) | catalogued as rs372123336; called by muse, varscan2
- STAB1 | c.5235+110G>A | Intron (SNP) | VAF 11/41 reads (27%) | catalogued as rs1265472618; called by muse, mutect2, varscan2
- TMEM250 | c.-409C>A | 5'UTR (SNP) | VAF 9/50 reads (18%) | called by muse, mutect2
- TMPRSS4 | c.*2818A>G | 3'UTR (SNP) | VAF 5/92 reads (5%) | called by muse, mutect2
- TRIM39 | c.*1390T>A | 3'UTR (SNP) | VAF 42/115 reads (37%) | called by muse, mutect2, varscan2
- TRIM67 | chr1:231220590 G>A | 3'Flank (SNP) | VAF 49/120 reads (41%) | catalogued as rs529817704; called by muse, mutect2, varscan2
- UGT1A6 | c.*381G>A | 3'UTR (SNP) | VAF 53/120 reads (44%) | called by muse, mutect2, varscan2
- VWC2L | c.*1459G>T | 3'UTR (SNP) | VAF 54/124 reads (44%) | called by muse, mutect2, varscan2
- ZBED4 | c.*1164T>A | 3'UTR (SNP) | VAF 11/31 reads (35%) | called by muse, varscan2
- ZBED4 | c.*1215T>A | 3'UTR (SNP) | VAF 10/26 reads (38%) | called by muse, varscan2
- ZNF516 | c.*4355T>A | 3'UTR (SNP) | VAF 14/119 reads (12%) | called by muse, mutect2, varscan2
